Gene-level copy-number profile of tumor specimen TARGET-20-PASBBE-04A from TARGET case TARGET-20-PASBBE, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.6 years (3,889 days).
Specimen TARGET-20-PASBBE-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.d03611ba-96f3-56a6-87cb-8484bb7deb8f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PASBBE-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 352 have no estimate.
https://portal.gdc.cancer.gov/files/12866d31-75c2-4041-8ac8-1cd800edbac5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,417; copy number 1: 879; copy number 2: 56,903; copy number 3: 70; copy number 4: 2.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,337,465, 4 genes: AL031432.2, RHD, SDHDP6, AL928711.1.
- chr1:198,777,861–198,985,506, 5 genes (within-gene range 0–1): MIR181A1HG, MIR181B1, MIR181A1, AC096631.2, AC096631.1.
- chr2:144,364,364–144,579,434, 9 genes (within-gene range 0–2): ZEB2, AC009951.5, AC009951.4, ZEB2-AS1, AC009951.2, AC009951.1, AC009951.3, AC009951.6, LINC01412.
- chr3:15,667,236–15,859,771, 1 gene (within-gene range 0–2): ANKRD28.
- chr3:15,731,877–15,738,809, 3 genes: AC090950.2, AC090950.1, RN7SL4P.
- chr8:60,516,936–60,623,644, 2 genes: RAB2A, AC068389.3.
- chr12:9,715,860–9,760,901, 2 genes: CLECL1, CD69.
- chr15:59,659,146–59,689,534, 2 genes (within-gene range 0–2): BNIP2, PIGHP1.
- chr15:92,883,413–93,027,996, 3 genes (within-gene range 0–2): AC013394.1, CHD2, MIR3175.
- chr17:78,674,048–78,841,441, 4 genes (within-gene range 0–2): CYTH1, AC099804.1, RNU6-638P, USP36.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 879. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
